Surgical pathology report (de-identified scan), TCGA case TCGA-VR-A8Q7, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VR-A8Q7-01A (Primary Tumor).

ICD-O-3
Carcinoma, squamous cell NOS
8070/3
Site: Esophagus, distal third C15.5
JWB/8/14

Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Esophagus (Distal third)

“Product of esophagectomy, gastrectomy and colectomy:
Squamous cell carcinoma, histologic grade 3, developed in esophagus, invading until serous layer, with uninvolved margins.
Absence of lymph-vascular and perineural invasion.
Gastric segment: moderate chronic gastritis, uninvolved by neoplasia.
Colonic segment: chronic colitis, uninvolved by neoplasia.

Lesser curvature lymph nodes:
Metastasis of squamous cell carcinoma with capsular perforation (3/25).

Greater curvature lymph nodes:
Uninvolved by neoplasia (0/9).

Omentum:
Uninvolved by neoplasia.

Appendix:
Reactive lymphoid hyperplasia.

Mesenteric lymph nodes:
Uninvolved by neoplasia (0/41).

Suprapyloric region:
Fibrofatty tissue uninvolved by neoplasia.

Hepatoduodenal ligament lymph nodes:
Uninvolved by neoplasia (0/2).

Intestinal segment (colon):
Uninvolved by neoplasia.

Reviews: Initials	JWA	Date Reviewed: 11/6/13

Source: NCI Genomic Data Commons file 9051a17e-a610-482b-be29-e0b75ab8eb1a (TCGA-VR-A8Q7.86C50A71-0DFF-4481-8F8C-B2ADA05FD26D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).